Gene-level copy-number profile of tumor specimen C3N-02423-01 (profiled together with C3N-02423-02) from CPTAC case C3N-02423, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G3; Age at diagnosis: 70.3 years (25,686 days).
Specimen C3N-02423-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c2205f51-6fc5-43d3-9e46-29d0a62434e0.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-02423-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,713 have no estimate.
https://portal.gdc.cancer.gov/files/14ee445c-f96e-4d2f-965a-174f4b7707ec

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 321; copy number 1: 21,445; copy number 2: 34,101; copy number 3: 2,697; copy number 4: 295; copy number 5: 6; copy number 6: 30; copy number 7: 10; copy number 11: 2; copy number 14: 3.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:49,960,249–49,969,625, 2 genes: DEFB114, DEFB113.
- chr19:22,286,441–22,317,176, 2 genes: ZNF729, BNIP3P31.
- chr19:54,189,938–54,199,971, 2 genes: TSEN34, AC245052.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 51 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:35,749,287–36,171,334, 26 genes, copy number 6: RGP1, MSMP, AL133410.2, AL133410.1, NPR2, SPAG8, HINT2, AL133410.3, TMEM8B, FAM221B, OR13E1P, OR13J1, NDUFA5P4, HRCT1, SPAAR, PGAM1P2, OR2S2, OR2S1P, YBX1P10, OR13C6P, OR13C7, OR2AM1P, RECK, AL138834.1, GLIPR2, CCIN.
- chr9:41,269,916–41,355,538, 6 genes, copy number 5: AL845472.1, PTGER4P2-CDK2AP2P2, CDK2AP2P1, MYO5BP1, AL354718.2, CDRT15P6.
- chr9:41,573,156–41,701,096, 9 genes, copy number 6–14: AL591926.3, SNORA70, AL591926.7, AL591926.6, AL591926.5, FAM242F, Y_RNA, AL591926.1, AL591926.4.
- chr9:61,190,003–61,642,494, 10 genes, copy number 7: SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3, FAM242D, Y_RNA.

Autosomal genes at a single copy (total copy number 1): 18,906. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
